Somatic mutation profile of tumor specimen 0DTB8X from CCDI case PBCJKR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.6 years (942 days).
Specimen 0DTB8X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af241e3f-41dd-40bc-ac90-bdaed2cac49c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23530fce-59c2-4dea-ad58-e6897061a05e

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBC1D22A | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 122/697 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs748273994; called by muse, mutect2, varscan2
- CHCHD3 | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 220/538 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LARP1 | c.1469A>T p.D490V (on ENST00000518297 / NM_033551.3; = p.D413V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/545 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DOCK4 | c.2325G>A p.L775= | Silent (SNP) | VAF 14/512 reads (3%) | catalogued as rs996916943; called by muse, mutect2
- MSLN | c.1808-38G>A | Intron (SNP) | VAF 45/247 reads (18%) | catalogued as rs374136251; called by muse, mutect2, varscan2
- PRSS55 | c.-34del | 5'UTR (DEL) | VAF 30/196 reads (15%) | called by mutect2, pindel, varscan2
